Somatic mutation profile of tumor specimen TCGA-5G-A9ZZ-01A (aliquot TCGA-5G-A9ZZ-01A-31D-A423-09) from TCGA case TCGA-5G-A9ZZ, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 52.3 years (19,117 days).
Specimen TCGA-5G-A9ZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cec76737-9a83-4d69-be8d-7d20b780554c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5G-A9ZZ-10A (Blood Derived Normal), aliquot TCGA-5G-A9ZZ-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef8849dc-d6ac-487c-a0b3-2c86947712be

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDCA3 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- EVL | c.206T>C p.L69P (on ENST00000402714 / NM_001330221.2; = p.L71P on NM_016337.3) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCAPD2 | c.4103A>G p.D1368G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NHS | c.2713C>A p.Q905K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- PDZRN4 | c.995C>G p.A332G (on ENST00000402685 / NM_001164595.2; = p.A74G on NM_013377.4) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PSTPIP1 | c.68A>T p.E23V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZKSCAN8 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP5 | c.4758G>A p.A1586= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs772806499; called by muse, mutect2, varscan2
- SYTL5 | c.1626A>G p.Q542= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs1450810606; called by muse, mutect2, varscan2
